Somatic mutation profile of tumor specimen TCGA-XE-AANI-01A (aliquot TCGA-XE-AANI-01A-11D-A435-10) from TCGA case TCGA-XE-AANI, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Teratocarcinoma; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 37.1 years (13,553 days).
Specimen TCGA-XE-AANI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1487b9df-5681-4b5b-ac81-a5f4ba7fdb0a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XE-AANI-10A (Blood Derived Normal), aliquot TCGA-XE-AANI-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8a52292-a734-4f89-907e-cb399c451ff6

The open-access MAF lists 29 somatic variants for this specimen: 16 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 10, Missense Mutation 9, Frame Shift Del 3, Nonsense Mutation 2, 5'UTR 1, In Frame Del 1, Splice Site 1, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL3 | c.1417C>T p.Q473* (on ENST00000506720 / NM_001322402.2; = p.Q405* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 28/84 reads (33%) | catalogued as COSV72274000; called by muse, mutect2, varscan2
- C5 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56328675; called by muse, mutect2, varscan2
- EGFR | c.3533C>T p.P1178L | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV51857489; called by muse, mutect2, varscan2
- PIDD1 | c.1088C>T p.P363L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs764139061, COSV61705568; called by muse, mutect2, varscan2
- SLC16A7 | c.517G>A p.G173S | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV53900561; called by muse, mutect2, varscan2
- DENND1C | c.1039_1048del p.L347Afs*6 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by mutect2, pindel, varscan2
- HUWE1 | c.8792C>A p.S2931Y | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- KLHDC3 | c.114T>G p.Y38* | Nonsense Mutation (SNP) | VAF 12/45 reads (27%) | called by muse, mutect2, varscan2
- KRT80 | c.763G>T p.V255L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- LRRD1 | c.715C>G p.L239V | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYH6 | c.503-2A>G p.X168_splice | Splice Site (SNP) | VAF 21/58 reads (36%) | called by muse, mutect2, varscan2
- RARS2 | c.564del p.F188Lfs*32 | Frame Shift Del (DEL) | VAF 7/35 reads (20%) | called by mutect2, pindel, varscan2
- TBC1D22A | c.805A>T p.N269Y | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- TET1 | c.563C>T p.T188I | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UBR2 | c.1062_1073del p.R354_L357del | In Frame Del (DEL) | VAF 13/67 reads (19%) | called by mutect2, pindel, varscan2
- ZSCAN10 | c.944_957del p.H315Lfs*91 (on ENST00000252463; = p.H370Lfs*91 on NM_032805.3) | Frame Shift Del (DEL) | VAF 4/23 reads (17%) | called by mutect2, pindel
- CNBD1 | c.1062T>C p.N354= | Silent (SNP) | VAF 11/68 reads (16%) | called by muse, mutect2, varscan2
- DNMT3A | c.186C>T p.S62= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as rs775703720, COSV53068730; called by muse, mutect2, varscan2
- FAN1 | c.2208G>A p.P736= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs141117593; called by muse, mutect2, varscan2
- PRKCSH | c.18G>T p.L6= | Silent (SNP) | VAF 10/23 reads (43%) | called by muse, mutect2, varscan2
- REM1 | c.186C>T p.A62= | Silent (SNP) | VAF 23/117 reads (20%) | called by muse, mutect2, varscan2
- SRCAP | c.1887G>A p.L629= | Silent (SNP) | VAF 16/63 reads (25%) | called by muse, mutect2, varscan2
- TBX18 | c.15A>T p.R5= | Silent (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
- TRPA1 | c.33T>A p.P11= | Silent (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2, varscan2
- TRPV4 | c.1785G>A p.G595= | Silent (SNP) | VAF 23/77 reads (30%) | called by muse, mutect2, varscan2
- UACA | c.693G>A p.A231= | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as rs762624989; called by muse, mutect2, varscan2
- ADIG | c.125-566T>G | Intron (SNP) | VAF 13/60 reads (22%) | called by muse, mutect2, varscan2
- CTDSP1 | c.-53G>T | 5'UTR (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2, varscan2
- ENDOV | chr17:80415146 C>T | 5'Flank (SNP) | VAF 10/33 reads (30%) | called by muse, mutect2, varscan2
